Somatic mutation profile of tumor specimen TCGA-HW-A5KL-01A (aliquot TCGA-HW-A5KL-01A-11D-A27K-08) from TCGA case TCGA-HW-A5KL, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 42.5 years (15,513 days).
Specimen TCGA-HW-A5KL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf74e4c2-5e1a-47f3-b5cf-337854f9c65e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-A5KL-10A (Blood Derived Normal), aliquot TCGA-HW-A5KL-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a3fa399-9c97-4f81-a345-15668a82c182

The open-access MAF lists 20 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 17, Frame Shift Del 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.695T>G p.I232S | Missense Mutation (SNP) | VAF 43/53 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs587781589, CM103212, COSV52661257, COSV52760307, COSV52829354; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALAS2 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1225585678, COSV58192087; called by muse, mutect2, varscan2
- ATRX | c.787T>C p.W263R | Missense Mutation (SNP) | VAF 115/220 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM005475, COSV64880174; called by muse, mutect2, varscan2
- CRAMP1 | c.3173C>T p.S1058F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV51964195; called by mutect2, varscan2
- CYP2B6 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs373086625, COSV57844907; called by muse, mutect2, varscan2
- DCAF12L2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63583117; called by muse, mutect2, varscan2
- EFHC2 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as rs763565690, COSV69554575; called by muse, mutect2, varscan2
- ERG | c.958C>T p.L320F (on ENST00000398919 / NM_001243428.1; = p.L296F on NM_004449.4) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55737271; called by muse, mutect2
- FANCM | c.3196C>G p.L1066V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV99950273; called by muse, mutect2
- GRIP2 | c.3389G>A p.R1130Q (on ENST00000619221; = p.R1033Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs181971811, COSV56123070; called by muse, varscan2
- IPO8 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377410854, COSV56243447; called by muse, mutect2, varscan2
- PLVAP | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV53086473; called by muse, mutect2, varscan2
- PLXNB3 | c.3433C>A p.Q1145K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV62799773; called by muse, mutect2, varscan2
- SPANXD | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs782056039, COSV100982228; called by muse, mutect2
- TTC17 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs758314443, COSV50013150; called by muse, mutect2, varscan2
- XYLT1 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV54490798; called by muse, mutect2, varscan2
- PPP2R5E | c.863_867del p.I288Tfs*15 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, varscan2
- RLIM | c.950dup p.T318Nfs*5 | Frame Shift Ins (INS) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- UBQLN2 | c.399C>T p.S133= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs776174680, COSV100592602; called by muse, mutect2, varscan2
